Somatic mutation profile of tumor specimen MMRF_2604_1_BM_CD138pos (aliquot MMRF_2604_1_BM_CD138pos_T1_KHS5U_L13292) from MMRF case MMRF_2604, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 62.5 years (22,823 days).
Specimen MMRF_2604_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fa382b13-389c-4a52-998a-5e64f8a4f478.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2604_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2604_1_PB_WBC_C3_KHS5U_L13293; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b3863f6e-95b2-4187-b7ea-a4acebc8f052

The open-access MAF lists 143 somatic variants for this specimen: 57 protein-altering or splice-affecting, 21 silent, 65 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, 3'UTR 37, Silent 21, Intron 19, Nonsense Mutation 4, 3'Flank 4, 5'UTR 3, Translation Start Site 1, 5'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR3 | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 55/111 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913482, CM950469, COSV53390662; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SCN2A | c.4303C>T p.R1435* | Nonsense Mutation (SNP) | VAF 6/15 reads (40%) | catalogued as rs796053138, CM165174; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS20 | c.154G>T p.G52* | Nonsense Mutation (SNP) | VAF 48/193 reads (25%) | catalogued as COSV101240175; called by muse, mutect2, varscan2
- BFAR | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 76/185 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); catalogued as COSV55493090; called by muse, mutect2, varscan2
- CLEC4F | c.600C>G p.F200L | Missense Mutation (SNP) | VAF 97/209 reads (46%) | SIFT tolerated (0.27); PolyPhen benign (0.012); catalogued as COSV55478073; called by muse, mutect2, varscan2
- CYP4F11 | c.1187C>T p.P396L | Missense Mutation (SNP) | VAF 132/375 reads (35%) | SIFT tolerated (0.42); PolyPhen benign (0.009); catalogued as rs141887211; called by muse, mutect2, varscan2
- DENND2B | c.1453G>A p.E485K | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as COSV58201378; called by muse, mutect2, varscan2
- DIS3 | c.2458C>T p.R820W | Missense Mutation (SNP) | VAF 112/121 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372878316; called by muse, mutect2, varscan2
- GFPT2 | c.1438A>G p.T480A | Missense Mutation (SNP) | VAF 49/378 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as rs751766251; called by muse, mutect2, varscan2
- IGLV3-25 | c.197T>C p.I66T | Missense Mutation (SNP) | VAF 78/162 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.455); catalogued as rs182651541; called by muse, varscan2
- KDR | c.2158C>T p.R720W | Missense Mutation (SNP) | VAF 61/116 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV55766144; called by muse, mutect2, varscan2
- KLRG2 | c.1151G>A p.G384E | Missense Mutation (SNP) | VAF 66/248 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.587); catalogued as rs1218084165, COSV61800901; called by muse, mutect2, varscan2
- LTBP3 | c.574G>A p.A192T | Missense Mutation (SNP) | VAF 25/309 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.978); catalogued as rs866479393; called by muse, mutect2
- OR52N5 | c.223C>G p.L75V | Missense Mutation (SNP) | VAF 90/180 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); catalogued as rs754087298; called by muse, mutect2, varscan2
- PAX1 | c.995C>T p.P332L | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.741); catalogued as COSV68271544; called by muse, mutect2, varscan2
- PCDHA10 | c.61G>A p.A21T | Missense Mutation (SNP) | VAF 124/232 reads (53%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.02); catalogued as rs781975666, COSV56485061; called by muse, mutect2, varscan2
- PLXNC1 | c.2965C>T p.R989W | Missense Mutation (SNP) | VAF 69/165 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs762807213; called by muse, mutect2, varscan2
- R3HDM2 | c.1636C>T p.R546C | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.482); catalogued as rs757842057, COSV61293693; called by muse, mutect2, varscan2
- SPATA31D4 | c.2564A>G p.K855R | Missense Mutation (SNP) | VAF 41/105 reads (39%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.948); catalogued as rs1345446025; called by muse, mutect2, varscan2
- SSX2IP | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 161/345 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as rs372690838; called by muse, mutect2, varscan2
- STK10 | c.2836G>T p.E946* | Nonsense Mutation (SNP) | VAF 43/189 reads (23%) | catalogued as COSV99452420; called by muse, mutect2, varscan2
- TMEM132B | c.2315C>G p.T772S | Missense Mutation (SNP) | VAF 95/222 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV54766285; called by muse, mutect2, varscan2
- TMEM132D | c.271C>T p.P91S | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765263700, COSV101398857; called by muse, mutect2
- TTC3 | c.4936G>C p.E1646Q | Missense Mutation (SNP) | VAF 6/146 reads (4%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.703); catalogued as COSV100695805; called by muse, mutect2
- XDH | c.2698C>T p.R900W | Missense Mutation (SNP) | VAF 47/121 reads (39%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.671); catalogued as rs763704314; called by muse, mutect2, varscan2
- ZNF721 | c.2558A>C p.Y853S (on ENST00000338977; = p.Y865S on NM_133474.4) | Missense Mutation (SNP) | VAF 60/121 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as COSV59093371; called by muse, mutect2, varscan2
- ARMC2 | c.301G>A p.V101I | Missense Mutation (SNP) | VAF 150/161 reads (93%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- ASTN2 | c.1599C>G p.C533W (on ENST00000313400 / NM_001365069.1; = p.C482W on NM_014010.5) | Missense Mutation (SNP) | VAF 17/158 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CAPN10 | c.1909G>A p.A637T | Missense Mutation (SNP) | VAF 80/170 reads (47%) | SIFT tolerated (0.66); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CDH20 | c.1019C>T p.P340L | Missense Mutation (SNP) | VAF 64/126 reads (51%) | SIFT tolerated (0.05); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- DMGDH | c.2324T>A p.L775H | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- EFHB | c.310C>G p.L104V | Missense Mutation (SNP) | VAF 153/346 reads (44%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- ESRP2 | c.1527G>A p.M509I (on ENST00000565858 / NM_001365264.1; = p.M499I on NM_024939.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/299 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2
- FIP1L1 | c.1508A>T p.E503V | Missense Mutation (SNP) | VAF 154/310 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- IGHV3-33 | c.109C>A p.L37M | Missense Mutation (SNP) | VAF 43/401 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.983); called by muse, varscan2
- NAMPT | c.431T>G p.L144R | Missense Mutation (SNP) | VAF 7/197 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- OR4Q3 | c.569T>C p.V190A | Missense Mutation (SNP) | VAF 83/246 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OTUD7A | c.1574G>C p.G525A (on ENST00000307050 / NM_001382637.1; = p.G518A on NM_130901.3) | Missense Mutation (SNP) | VAF 31/331 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PAQR8 | c.377G>C p.S126T | Missense Mutation (SNP) | VAF 12/272 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCDHGA2 | c.767T>C p.L256P | Missense Mutation (SNP) | VAF 78/167 reads (47%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PIAS1 | c.1006C>G p.P336A | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- POLR1E | c.822C>A p.D274E (on ENST00000377792 / NM_001282766.1; = p.D212E on NM_022490.4) | Missense Mutation (SNP) | VAF 37/290 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- PRMT6 | c.250A>G p.K84E | Missense Mutation (SNP) | VAF 124/231 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RBM10 | c.1033T>G p.F345V | Missense Mutation (SNP) | VAF 75/77 reads (97%) | SIFT tolerated (0.05); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- RTN3 | c.853G>T p.E285* (on ENST00000377819 / NM_001265589.2; = p.E266* on NM_201428.3) | Nonsense Mutation (SNP) | VAF 28/273 reads (10%) | called by muse, mutect2, varscan2
- RXFP4 | c.600G>T p.W200C | Missense Mutation (SNP) | VAF 83/135 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SI | c.2969A>T p.Y990F | Missense Mutation (SNP) | VAF 21/191 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- SKIDA1 | c.2114A>G p.N705S | Missense Mutation (SNP) | VAF 23/224 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SP140 | c.2534G>C p.R845T | Missense Mutation (SNP) | VAF 73/169 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- SSTR3 | c.616T>G p.F206V | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TET3 | c.3026A>G p.D1009G | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TINAG | c.1163A>G p.K388R | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT tolerated (0.22); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- TNFSF13B | c.119G>A p.R40Q | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- TPR | c.6623G>T p.G2208V | Missense Mutation (SNP) | VAF 63/206 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TRDMT1 | c.709G>C p.E237Q | Missense Mutation (SNP) | VAF 46/87 reads (53%) | SIFT tolerated (0.08); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- USH2A | c.3517T>A p.S1173T | Missense Mutation (SNP) | VAF 318/481 reads (66%) | SIFT tolerated (0.15); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- VPS9D1 | c.743A>G p.D248G | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ALMS1 | c.7281G>A p.S2427= | Silent (SNP) | VAF 102/210 reads (49%) | catalogued as rs200684911; ClinVar: likely benign; called by mutect2, varscan2
- APBA3 | c.1236G>A p.S412= | Silent (SNP) | VAF 46/146 reads (32%) | catalogued as rs766395163; called by muse, mutect2, varscan2
- AXIN2 | c.1305G>A p.P435= | Silent (SNP) | VAF 47/86 reads (55%) | catalogued as rs369221405; ClinVar: benign / likely benign; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.1704G>A p.L568= | Silent (SNP) | VAF 74/80 reads (93%) | catalogued as rs775375910; called by muse, mutect2, varscan2
- CNGB3 | c.1998C>T p.F666= | Silent (SNP) | VAF 47/97 reads (48%) | called by muse, mutect2, varscan2
- FAM193A | c.2400C>T p.G800= | Silent (SNP) | VAF 104/241 reads (43%) | catalogued as COSV61191664, COSV61199082; called by muse, mutect2, varscan2
- FGD4 | c.96A>G p.S32= | Silent (SNP) | VAF 117/130 reads (90%) | called by muse, mutect2, varscan2
- HTR3E | c.490C>T p.L164= (on ENST00000415389 / NM_001256613.1; = p.L179= on NM_182589.2) | Silent (SNP) | VAF 44/107 reads (41%) | called by muse, mutect2, varscan2
- IGHD1-7 | c.3T>C p.G1= | Silent (SNP) | VAF 21/21 reads (100%) | catalogued as rs572280869; called by muse, mutect2, varscan2
- KAT6B | c.447G>A p.Q149= | Silent (SNP) | VAF 77/175 reads (44%) | catalogued as rs776337217; called by muse, mutect2, varscan2
- MAP3K21 | c.1611G>A p.L537= | Silent (SNP) | VAF 22/316 reads (7%) | catalogued as COSV64042685; called by muse, mutect2
- MAPK8IP2 | c.855C>T p.S285= | Silent (SNP) | VAF 16/42 reads (38%) | called by muse, mutect2, varscan2
- NRBP1 | c.711G>A p.Q237= | Silent (SNP) | VAF 46/120 reads (38%) | called by muse, mutect2, varscan2
- OR10AG1 | c.387C>T p.H129= | Silent (SNP) | VAF 12/226 reads (5%) | called by muse, mutect2
- PHLDA1 | c.1131A>T p.I377= | Silent (SNP) | VAF 54/109 reads (50%) | called by muse, mutect2, varscan2
- RBP3 | c.2013C>T p.G671= | Silent (SNP) | VAF 41/92 reads (45%) | catalogued as rs782532814; called by muse, mutect2, varscan2
- STAB1 | c.5631G>A p.E1877= | Silent (SNP) | VAF 10/142 reads (7%) | called by muse, mutect2
- SUSD5 | c.402G>A p.K134= | Silent (SNP) | VAF 86/212 reads (41%) | catalogued as COSV100535138; called by muse, mutect2, varscan2
- USP44 | c.282C>T p.D94= | Silent (SNP) | VAF 129/267 reads (48%) | called by muse, mutect2, varscan2
- XBP1 | c.525G>A p.Q175= | Silent (SNP) | VAF 16/98 reads (16%) | called by muse, mutect2, varscan2
- ZNF574 | c.1974C>T p.A658= | Silent (SNP) | VAF 65/102 reads (64%) | catalogued as rs144331239; called by muse, mutect2, varscan2
- AC105101.2 | n.1055-880A>T | Intron (SNP) | VAF 101/185 reads (55%) | called by muse, mutect2
- ACTBL2 | c.*869G>A | 3'UTR (SNP) | VAF 9/18 reads (50%) | called by muse, mutect2, varscan2
- ADNP | chr20:50890199 ins ATTCTATTTG | 3'Flank (INS) | VAF 40/76 reads (53%) | called by mutect2, varscan2
- AFF3 | c.*159T>C | 3'UTR (SNP) | VAF 47/105 reads (45%) | called by muse, mutect2, varscan2
- AGBL4 | c.1267+325T>C | Intron (SNP) | VAF 41/108 reads (38%) | called by muse, mutect2, varscan2
- AL031777.2 | chr6:26196659 G>A | 3'Flank (SNP) | VAF 28/48 reads (58%) | called by muse, mutect2, varscan2
- ANXA2R | c.-797T>A | 5'UTR (SNP) | VAF 73/136 reads (54%) | called by muse, mutect2, varscan2
- C20orf204 | c.280-44G>T | Intron (SNP) | VAF 16/37 reads (43%) | called by muse, mutect2, varscan2
- C8orf86 | n.1510G>T | RNA (SNP) | VAF 33/69 reads (48%) | called by muse, mutect2, varscan2
- CACNB4 | c.*900A>G | 3'UTR (SNP) | VAF 9/137 reads (7%) | catalogued as rs1264286319; called by muse, mutect2
- CDH11 | c.*2319T>A | 3'UTR (SNP) | VAF 5/15 reads (33%) | called by muse, mutect2
- COL11A1 | c.3168+112G>A | Intron (SNP) | VAF 20/37 reads (54%) | called by muse, mutect2, varscan2
- CUX1 | c.*8696A>C | 3'UTR (SNP) | VAF 33/134 reads (25%) | called by muse, mutect2, varscan2
- CYP3A7-CYP3A51P | c.1498-4166C>T | Intron (SNP) | VAF 67/285 reads (24%) | catalogued as rs1317190698; called by muse, mutect2, varscan2
- DCTN5 | c.*1576C>T | 3'UTR (SNP) | VAF 68/132 reads (52%) | called by muse, mutect2, varscan2
- ELP2 | c.445+53A>T | Intron (SNP) | VAF 5/45 reads (11%) | called by muse, mutect2
- EMSY | chr11:76552228 G>T | 3'Flank (SNP) | VAF 14/34 reads (41%) | called by muse, varscan2
- FAM133A | c.*1329T>G | 3'UTR (SNP) | VAF 17/18 reads (94%) | called by muse, mutect2, varscan2
- FAM160B1 | c.*404A>T | 3'UTR (SNP) | VAF 37/73 reads (51%) | called by muse, mutect2, varscan2
- GABRA4 | c.*5566T>G | 3'UTR (SNP) | VAF 35/66 reads (53%) | called by muse, mutect2, varscan2
- GLI3 | c.*1493T>C | 3'UTR (SNP) | VAF 45/112 reads (40%) | called by muse, mutect2, varscan2
- GLP1R | c.*991C>A | 3'UTR (SNP) | VAF 65/130 reads (50%) | called by muse, mutect2, varscan2
- GSK3A | c.*277G>C | 3'UTR (SNP) | VAF 4/14 reads (29%) | called by muse, mutect2
- GULP1 | c.399+103T>G | Intron (SNP) | VAF 16/30 reads (53%) | called by muse, mutect2, varscan2
- HMGCLL1 | c.632+1765A>G | Intron (SNP) | VAF 7/63 reads (11%) | called by muse, mutect2, varscan2
- IGF2BP2 | c.240-23823C>T | Intron (SNP) | VAF 10/25 reads (40%) | catalogued as rs1405180710; called by muse, mutect2
- KCNA4 | c.*635A>T | 3'UTR (SNP) | VAF 11/21 reads (52%) | called by muse, mutect2, varscan2
- KCNS2 | c.*2427C>T | 3'UTR (SNP) | VAF 4/74 reads (5%) | catalogued as rs1381881910; called by muse, mutect2
- LAMB3 | c.*182G>A | 3'UTR (SNP) | VAF 41/140 reads (29%) | called by muse, mutect2, varscan2
- MARK1 | c.*744T>A | 3'UTR (SNP) | VAF 71/103 reads (69%) | called by muse, mutect2, varscan2
- METTL17 | c.364+106G>T | Intron (SNP) | VAF 15/27 reads (56%) | called by muse, mutect2, varscan2
- MIDEAS | c.*1207G>A | 3'UTR (SNP) | VAF 90/150 reads (60%) | catalogued as rs548330526; called by muse, mutect2, varscan2
- MMS19 | c.2312-160G>C | Intron (SNP) | VAF 6/12 reads (50%) | called by muse, mutect2, varscan2
- NAV3 | c.*180A>G | 3'UTR (SNP) | VAF 26/75 reads (35%) | called by muse, mutect2, varscan2
- NCK2 | c.*839_*846del | 3'UTR (DEL) | VAF 6/42 reads (14%) | catalogued as rs200741542; called by mutect2, varscan2
- NDE1 | c.-44+753G>A | Intron (SNP) | VAF 12/17 reads (71%) | catalogued as rs1181679311; called by muse, mutect2, varscan2
- NHLH2 | c.-403G>A | 5'UTR (SNP) | VAF 65/112 reads (58%) | catalogued as rs1018218749, COSV57202325, COSV57203093; called by muse, mutect2, varscan2
- NHLH2 | chr1:115843414 T>G | 5'Flank (SNP) | VAF 26/63 reads (41%) | called by muse, mutect2, varscan2
- NPTXR | c.*1820C>A | 3'UTR (SNP) | VAF 85/175 reads (49%) | called by muse, mutect2, varscan2
- NUP153 | c.*687T>G | 3'UTR (SNP) | VAF 9/99 reads (9%) | called by muse, mutect2
- OR5T1 | c.-125C>T | 5'UTR (SNP) | VAF 91/215 reads (42%) | called by muse, mutect2, varscan2
- PAQR8 | c.*58T>A | 3'UTR (SNP) | VAF 15/306 reads (5%) | called by muse, mutect2
- PAQR8 | c.*1588A>C | 3'UTR (SNP) | VAF 8/76 reads (11%) | called by muse, mutect2, varscan2
- PKHD1 | c.10156+23477del | Intron (DEL) | VAF 13/50 reads (26%) | called by mutect2, pindel, varscan2
- PPP1R9A | c.*5664A>C | 3'UTR (SNP) | VAF 45/70 reads (64%) | called by muse, mutect2, varscan2
- RARRES1 | c.*295G>A | 3'UTR (SNP) | VAF 32/82 reads (39%) | called by muse, mutect2
- RFX5 | c.*1180G>C | 3'UTR (SNP) | VAF 21/175 reads (12%) | called by muse, mutect2, varscan2
- RGS4 | c.*422G>A | 3'UTR (SNP) | VAF 38/58 reads (66%) | called by muse, mutect2, varscan2
- RIMS2 | chr8:104255400 C>T | 3'Flank (SNP) | VAF 20/134 reads (15%) | catalogued as rs1387611763; called by muse, mutect2, varscan2
- SAMD7 | c.291-239G>A | Intron (SNP) | VAF 12/94 reads (13%) | catalogued as rs183002604; called by muse, mutect2, varscan2
- SELENOH | c.268+31G>T | Intron (SNP) | VAF 27/92 reads (29%) | called by muse, mutect2, varscan2
- SEMA3E | c.*853C>T | 3'UTR (SNP) | VAF 40/68 reads (59%) | called by muse, mutect2, varscan2
- SH2D3C | c.*365T>C | 3'UTR (SNP) | VAF 81/144 reads (56%) | called by muse, mutect2, varscan2
- SLC6A15 | c.*1936T>G | 3'UTR (SNP) | VAF 8/18 reads (44%) | called by muse, mutect2, varscan2
- SLIT1 | c.*1089G>T | 3'UTR (SNP) | VAF 60/109 reads (55%) | called by muse, mutect2, varscan2
- SSPOP | n.7281-12C>T | Intron (SNP) | VAF 7/144 reads (5%) | called by muse, mutect2
- STAM | c.*601C>A | 3'UTR (SNP) | VAF 13/31 reads (42%) | called by muse, mutect2, varscan2
- STMP1 | c.*255G>A | 3'UTR (SNP) | VAF 11/41 reads (27%) | called by muse, mutect2, varscan2
- TCF7L2 | c.*173T>G | 3'UTR (SNP) | VAF 34/74 reads (46%) | called by muse, mutect2, varscan2
- TNPO1 | c.*967A>G | 3'UTR (SNP) | VAF 72/153 reads (47%) | called by muse, mutect2, varscan2
- TSPYL4 | c.*2241C>G | 3'UTR (SNP) | VAF 41/47 reads (87%) | called by muse, mutect2
- USP22 | c.*818T>A | 3'UTR (SNP) | VAF 137/285 reads (48%) | called by muse, mutect2, varscan2
- WDR33 | c.725-9377T>A | Intron (SNP) | VAF 26/54 reads (48%) | called by muse, mutect2, varscan2
- WSCD2 | c.1144+16G>A | Intron (SNP) | VAF 45/96 reads (47%) | called by muse, mutect2, varscan2
- ZBTB44 | c.*48+405A>C | Intron (SNP) | VAF 3/11 reads (27%) | called by muse, mutect2
